CCDI case PBCFUI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fffc3dd3-f69f-48cd-8786-2abf994fa70e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Chordoma, NOS: ICD-O-3 morphology code: 9370/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,367 days).

Biospecimens (3 samples)
- Sample 0DQWRM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQWS3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQWS5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
